Somatic mutation profile of cancer-model specimen HCM-BROD-0559-C16-85M (3D Organoid, passage 5; aliquot HCM-BROD-0559-C16-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0559-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 24.3 years (8,881 days).
Specimen HCM-BROD-0559-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64925070-5db9-486f-9610-32ee046b1172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0559-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0559-C16-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b3bae6b-8ce7-4b2e-b979-0fc6c5d8bab3

The open-access MAF lists 96 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 26, Nonsense Mutation 5, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 223/223 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52675774, COSV52680475, COSV52702460, COSV53452020; called by muse, mutect2, varscan2
- APOB | c.12335C>G p.A4112G | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV51932095; called by muse, mutect2, varscan2
- ATXN2 | c.3556A>G p.S1186G (on ENST00000550104; = p.S1026G on NM_002973.4) | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1207815388; called by muse, mutect2, varscan2
- AURKC | c.748C>T p.R250C (on ENST00000302804 / NM_001015878.2; = p.R216C on NM_003160.3) | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs780990641; called by muse, mutect2, varscan2
- CFAP65 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 83/470 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV58559375; called by muse, mutect2, varscan2
- CLNS1A | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 20/256 reads (8%) | catalogued as rs963821795; called by muse, mutect2
- DIPK2B | c.520C>A p.R174S | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs1214905060; called by muse, mutect2, varscan2
- DMD | c.711A>C p.Q237H | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs778632674, COSV55856238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBPL | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757958154; called by muse, mutect2, varscan2
- FLT1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1412060347, COSV56725485; called by muse, mutect2, varscan2
- FNDC3B | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs139658890; called by muse, mutect2, varscan2
- GALNT12 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 180/180 reads (100%) | catalogued as COSV66662155; called by muse, mutect2, varscan2
- KIF26A | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs781186307; called by muse, mutect2, varscan2
- KLHL14 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 212/357 reads (59%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.921); catalogued as rs1410508719, COSV100809208; called by muse, mutect2, varscan2
- LCE3E | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 529/856 reads (62%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as rs1366616392; called by muse, mutect2, varscan2
- LRP1B | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 98/193 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67246937; called by muse, mutect2, varscan2
- NAT10 | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs766956292, COSV57665597; called by muse, mutect2, varscan2
- NSMAF | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.827); catalogued as COSV50689400; called by muse, mutect2, varscan2
- OBSCN | c.15212C>T p.A5071V | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375341687; called by muse, mutect2, varscan2
- PRKAG2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 16/579 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs876657963, COSV55236280; ClinVar: uncertain significance; called by muse, mutect2
- PRX | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1040753771; called by muse, mutect2
- PTEN | c.402_404del p.M134del | In Frame Del (DEL) | VAF 163/167 reads (98%) | catalogued as rs1554898152; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PUS7 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 27/698 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV62677666, COSV62678783; called by muse, mutect2
- RABL6 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 161/162 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs758669107; called by muse, mutect2, varscan2
- ROCK1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 103/194 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765332481; called by muse, mutect2, varscan2
- TMEFF2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749549984, COSV55828645; called by muse, mutect2, varscan2
- ZAN | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 194/608 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.127); catalogued as rs751470697, COSV100769007; called by muse, mutect2, varscan2
- ADAMTS8 | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 48/555 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADARB2 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 281/613 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGFG1 | c.1593A>C p.Q531H | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ANKEF1 | c.1668C>A p.N556K | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- ATP13A3 | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 168/486 reads (35%) | called by muse, mutect2, varscan2
- BCAN | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 703/981 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BORA | c.1241G>C p.S414T (on ENST00000613797; = p.S339T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/822 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- C11orf95 | c.1858C>T p.H620Y | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- C8G | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CATSPERD | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH18 | c.2298C>A p.Y766* | Nonsense Mutation (SNP) | VAF 162/345 reads (47%) | called by muse, mutect2, varscan2
- CLEC18C | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 235/565 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPSF1 | c.3758T>C p.L1253P | Missense Mutation (SNP) | VAF 410/723 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CTNND1 | c.423C>G p.V141= | Splice Region (SNP) | VAF 14/132 reads (11%) | called by muse, varscan2
- CYP51A1 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 58/636 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- DOCK8 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by mutect2, varscan2
- EMILIN2 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.074); called by muse, mutect2
- ETAA1 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- FAM53B | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 53/866 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- FBXO34 | c.2018A>G p.K673R | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- HDGF | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 311/1069 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT122 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IGKV3D-11 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 28/617 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.176); called by muse, mutect2
- KIAA1671 | c.5294G>T p.G1765V | Missense Mutation (SNP) | VAF 264/562 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLK12 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 118/883 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLKB1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KRTAP4-8 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 21/449 reads (5%) | called by muse, mutect2
- LZTR1 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 97/508 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MIPEP | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NRXN1 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OSGIN2 | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PARP4 | c.3412G>C p.D1138H | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PIK3C2B | c.3717_3720dup p.A1241Hfs*9 | Frame Shift Ins (INS) | VAF 1692/2055 reads (82%) | called by mutect2, pindel, varscan2
- PLXNC1 | c.2630T>C p.I877T | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- PMS1 | c.1388A>G p.K463R | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.052); called by muse, mutect2
- PREX2 | c.4412A>C p.K1471T | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SLC4A3 | c.3158C>G p.S1053C | Missense Mutation (SNP) | VAF 140/619 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPRA1 | c.82C>G p.H28D | Missense Mutation (SNP) | VAF 22/331 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- TRPM3 | c.3599A>T p.E1200V (on ENST00000357533 / NM_001366142.2; = p.E1055V on NM_020952.6) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- VEZT | c.2092G>T p.D698Y | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- ZNF521 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG11 | c.1200T>C p.F400= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as COSV73000558; called by muse, mutect2
- ANKFY1 | c.2169G>C p.G723= (on ENST00000341657 / NM_001330063.2; = p.G724= on NM_016376.5) | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2, varscan2
- BCR | c.3666T>G p.P1222= | Silent (SNP) | VAF 269/535 reads (50%) | called by muse, mutect2, varscan2
- CDH10 | c.2286C>T p.Y762= | Silent (SNP) | VAF 168/327 reads (51%) | catalogued as rs775096429, COSV52580162; called by muse, mutect2, varscan2
- COL12A1 | c.8541C>T p.D2847= | Silent (SNP) | VAF 159/326 reads (49%) | called by muse, mutect2, varscan2
- CPS1 | c.813A>G p.A271= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- DPYD | c.822A>G p.K274= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- FBXL7 | c.1335C>A p.G445= | Silent (SNP) | VAF 229/442 reads (52%) | called by muse, mutect2, varscan2
- GAN | c.1749G>A p.L583= | Silent (SNP) | VAF 187/390 reads (48%) | catalogued as rs1299781320; called by muse, mutect2, varscan2
- HIPK2 | c.2361G>A p.V787= | Silent (SNP) | VAF 72/810 reads (9%) | called by muse, mutect2
- IKZF1 | c.1518G>A p.S506= | Silent (SNP) | VAF 170/512 reads (33%) | catalogued as rs1301862364, COSV58783994; called by muse, varscan2
- KCNJ1 | c.684A>C p.G228= | Silent (SNP) | VAF 18/506 reads (4%) | called by muse, mutect2
- KIF16B | c.1542G>C p.L514= | Silent (SNP) | VAF 218/440 reads (50%) | called by muse, mutect2, varscan2
- LILRB2 | c.1299C>A p.I433= | Silent (SNP) | VAF 207/657 reads (32%) | catalogued as COSV100079719; called by mutect2, varscan2
- MAP3K10 | c.2088G>A p.A696= | Silent (SNP) | VAF 284/793 reads (36%) | catalogued as rs1466970151; called by muse, mutect2, varscan2
- PDE3B | c.2115A>G p.Q705= | Silent (SNP) | VAF 28/162 reads (17%) | called by mutect2, varscan2
- PLG | c.1656C>T p.Y552= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as rs113153850; called by muse, mutect2, varscan2
- PPFIBP1 | c.198G>A p.E66= | Silent (SNP) | VAF 24/476 reads (5%) | called by muse, mutect2
- PRR15 | c.66G>A p.K22= | Silent (SNP) | VAF 305/1043 reads (29%) | called by muse, mutect2, varscan2
- PTPN23 | c.1629G>A p.P543= | Silent (SNP) | VAF 169/169 reads (100%) | catalogued as rs771147465; called by muse, mutect2, varscan2
- SLC22A25 | c.105T>G p.T35= | Silent (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- SPHKAP | c.3249C>T p.C1083= | Silent (SNP) | VAF 30/501 reads (6%) | catalogued as rs758211060; called by muse, mutect2
- ST8SIA4 | c.528G>A p.E176= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV51515147; called by muse, mutect2, varscan2
- USP17L3 | c.357T>G p.R119= | Silent (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- ZNF560 | c.600T>C p.N200= | Silent (SNP) | VAF 134/134 reads (100%) | called by muse, mutect2, varscan2
- ZNF676 | c.432A>G p.V144= (on ENST00000650058; = p.V112= on NM_001001411.3) | Silent (SNP) | VAF 138/341 reads (40%) | called by muse, mutect2, varscan2
- DENND4B | c.-148del | 5'UTR (DEL) | VAF 402/859 reads (47%) | catalogued as rs1392401576; called by mutect2, pindel, varscan2
- KCTD1 | c.-15-47001G>A | Intron (SNP) | VAF 144/430 reads (33%) | called by muse, varscan2
